Gene-level copy-number profile of tumor specimen TCGA-38-4627-01A from TCGA case TCGA-38-4627, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 64.4 years (23,510 days).
Specimen TCGA-38-4627-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.e1d94da9-ee6f-4075-af4f-3f3b2d775dc8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-38-4627-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (sample pair TCGA-38-4627-01A|TCGA-38-4627-10A) (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/01dc6803-4dfb-40f1-a92c-e212b52e0768

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 174; copy number 2: 56,218; copy number 3: 3,426.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-38-4627-01A-01D-1549-01): tumor purity 0.22, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 174. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
